Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T2, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T2-01A (Primary Tumor).

[page 1 of 2]
		3/30/12

Pathology
Port

DOB:
Physician:

Age:

Sex

Collected:

Received:

Case type: Surgical Case

Accession:

DIAGNOSIS

- (A) RIGHT NECK LEVEL 3, DISSECTION:
METASTATIC PAPILLARY CARCINOMA IN TWO OF FIVE LYMPH NODES.
(0.8 CM LARGER FOCUS).
- (B) RIGHT NECK LEVEL 4, DISSECTION:
Two lymph nodes negative for tumor (0/2).
- (C) RIGHT NECK LEVEL 5, DISSECTION:
Four lymph nodes negative for tumor (0/4).
- (D) THYROID, TOTAL THYROIDECTOMY:
PAPILLARY CARCINOMA OF THYROID IN RIGHT LOBE, WITH FOLLICULAR COMPONENT.
Follicular adenoma, left lobe (1.7 cm in largest dimension).
- (E) LEFT PARATRACHEAL MASS, EXCISION:
METASTATIC PAPILLARY CARCINOMA IN SOFT TISSUE
Three lymph nodes negative for tumor (0/3).

Entire report and diagnosis completed by

ICD-O-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS
C73.9 4-3-12
KO

GROSS DESCRIPTION

- (A) RIGHT NECK LEVEL 3 – Level 3 measuring (4.0 x 2.0 x 1.0 cm). Identified five lymph nodes ranging in size (0.4 x 0.2 x 0.2 to 1.5 x 1.0 x 1.0 cm).
SECTION CODE: A1, one lymph node bisected; A2, one lymph node; A3, three lymph nodes.
- (B) RIGHT NECK LEVEL 4 – Level 4 measuring (5.0 x 2.5 x 0.5 cm). An irregular fragment of skeletal muscle (4.0 x 1.0 x 0.3 cm). Identified two lymph nodes (1.0 x 0.4 x 0.3 and 1.7 x 0.5 x 0.4 cm).
SECTION CODE: B1, representative sections of skeletal muscle; B2, one lymph node bisected; B3, one lymph node bisected.
- (C) RIGHT NECK LEVEL 5 – Level 5 measuring (3.0 x 2.0 x 0.8 cm). Identified four lymph nodes ranging in size from 0.2 x 0.2 x 0.2 to 0.3 x 0.2 x 0.2 cm).
SECTION CODE: C, four lymph nodes.
- (D) TOTAL THYROIDECTOMY – A total thyroidectomy with right lobe (3.0 x 1.5 x 1.7 cm), left lobe (3.5 x 2.5 x 1.9 cm), and isthmus (0.9 x 3.0 x 0.2 cm).
There is a well-circumscribed focally encapsulated tumor nodule (1.0 cm in greatest dimension) located in the middle to lower pole of the right lobe. The cut surface is somewhat septate with focal fleshy to papillary, tan-gray areas and focally cystic and calcified.

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician.

Age: Sex.

Collected
Received: (

Pathologist:
Case type: Surgical Case

Accession:

A second well-circumscribed and encapsulated tumor nodule (1.7 cm in maximum dimension) is present in the middle portion of the left thyroid lobe. The cut surface is somewhat similar to the first tumor nodule, but appears a little bit more colloid. The non-neoplastic thyroid parenchyma is gray-brown and fleshy.

INK CODE: Black - anterior surface. Blue - posterior surface of the thyroid gland.

SECTION CODE: D1-D7, right thyroid lobe including the entire nodule; D8-D15, left thyroid lobe including the entire nodule.

Small portions of both nodules and the non-neoplastic thyroid are submitted to the

(E) LEFT PARATRACHEAL MASS - A moderately firm soft tissue nodule, 2.5 x 1.8 x 1.2 cm. The cut surface is focally solid demonstrating tan-pink papillary tumor and focally cystic. Areas of calcifications are identified around the solid tumor.

SECTION CODE: E1-E3, entire specimen serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

T-C4200, M-80503, M-80506

Released by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file 801196d1-fa15-4ea6-8dcf-23ef7163ef2e (TCGA-EL-A3T2.8C7BD4A3-B00C-4D06-88B1-6C3164E36E99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).